Somatic mutation profile of tumor specimen TCGA-BL-A13I-01A (aliquot TCGA-BL-A13I-01A-11D-A13W-08) from TCGA case TCGA-BL-A13I, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 57.2 years (20,885 days).
Specimen TCGA-BL-A13I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15b5435c-7017-4f19-a893-dfd27d9fd248.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BL-A13I-10A (Blood Derived Normal), aliquot TCGA-BL-A13I-10A-01D-A271-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20a1e1db-e5f1-4172-bf05-5f6635b83a1b

The open-access MAF lists 110 somatic variants for this specimen: 88 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 78, Silent 22, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by mutect2, varscan2
- NFE2L2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.5050A>C p.S1684R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101315678; called by muse, mutect2
- AP002748.5 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 52/270 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs757307889, COSV59149588; called by muse, mutect2, varscan2
- ARID1B | c.3943C>T p.Q1315* | Nonsense Mutation (SNP) | VAF 37/217 reads (17%) | catalogued as rs1554234415, COSV99268166; called by muse, mutect2, varscan2
- ATP5PO | c.467A>T p.E156V | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51708572; called by muse, mutect2, varscan2
- ATXN2L | c.3056C>T p.S1019L | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV57372553; called by muse, varscan2
- B3GNTL1 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57950088; called by muse, varscan2
- BAG4 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54860069; called by muse, mutect2, varscan2
- BNC2 | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV101032590; called by muse, mutect2, varscan2
- C2orf42 | c.25A>G p.K9E | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV52450763; called by muse, mutect2, varscan2
- CAMKK2 | c.797-1G>A p.X266_splice | Splice Site (SNP) | VAF 7/40 reads (18%) | catalogued as COSV61215366; called by muse, mutect2, varscan2
- CATSPER2 | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 57/356 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs763965666, COSV58661086; called by muse, mutect2, varscan2
- CD163 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs748750295, COSV63133563; called by muse, mutect2, varscan2
- CDH16 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs140255974; called by muse, mutect2, varscan2
- CEP135 | c.3136C>T p.H1046Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV57260671; called by muse, mutect2, varscan2
- CFAP70 | c.2248C>G p.Q750E | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV60282023, COSV60283998; called by muse, mutect2
- CHD7 | c.7369A>T p.N2457Y | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV71111909; called by muse, mutect2, varscan2
- CIAPIN1 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200237459, COSV67953414; called by muse, mutect2, varscan2
- COMMD6 | c.61G>C p.D21H | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63322558; called by muse, mutect2, varscan2
- CTNND2 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV58896469; called by muse, mutect2, varscan2
- CYP2C9 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs150435881, COSV53246052; called by muse, mutect2, varscan2
- CYP2U1 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60549066; called by muse, mutect2, varscan2
- DDX3X | c.1058A>T p.D353V (on ENST00000399959; = p.D354V on NM_001356.5) | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67863257, COSV67863269; called by muse, mutect2, varscan2
- DISP1 | c.3921G>C p.Q1307H | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV52657899, COSV52660492; called by muse, mutect2, varscan2
- FAM186B | c.344T>C p.I115T | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as rs771352682, COSV57721893; called by muse, mutect2, varscan2
- FAT1 | c.6828C>G p.I2276M | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as COSV71674673; called by muse, mutect2, varscan2
- FOS | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771351750, COSV57839117; called by mutect2, varscan2
- FREM2 | c.4723G>A p.V1575M | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV54841008; called by muse, mutect2, varscan2
- GABRA1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1164973274, COSV50099709, COSV50102525; called by muse, varscan2
- GHSR | c.36C>G p.F12L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV53840039; called by muse, mutect2, varscan2
- HERC1 | c.7057G>C p.E2353Q | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.616); catalogued as COSV71247063, COSV71248400; called by muse, mutect2, varscan2
- IDE | c.817A>C p.K273Q | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV56424347; called by muse, mutect2, varscan2
- IL16 | c.3020C>G p.S1007C (on ENST00000302987 / NM_172217.5; = p.S306C on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV57264590; called by muse, varscan2
- KMT2C | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.782); catalogued as COSV51451790; called by mutect2, varscan2
- LAMA3 | c.7274C>G p.S2425* (on ENST00000313654 / NM_198129.4; = p.S816* on NM_000227.6) | Nonsense Mutation (SNP) | VAF 17/109 reads (16%) | catalogued as COSV52541290; called by muse, mutect2, varscan2
- LTBP1 | c.2784G>C p.Q928H (on ENST00000404816 / NM_206943.4; = p.Q602H on NM_000627.4) | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV63189789; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1345G>C p.D449H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.95); catalogued as COSV100824942, COSV64055959; called by muse, mutect2
- MRGPRX2 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.656); catalogued as COSV61674328; called by muse, mutect2, varscan2
- MS4A8 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs148191741; called by muse, mutect2, varscan2
- MYH4 | c.871C>G p.Q291E | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55115570, COSV55120002; called by muse, mutect2, varscan2
- NBPF1 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 88/624 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as rs758682530, COSV99844283; called by muse, mutect2, varscan2
- NCAM1 | c.2510C>A p.A837E (on ENST00000316851 / NM_181351.5; = p.A827E on NM_000615.7) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV100377262; called by muse, mutect2, varscan2
- NINL | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV99625006; called by muse, mutect2, varscan2
- NRBP1 | c.224A>G p.N75S | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV51994616; called by muse, mutect2
- NUFIP2 | c.1477C>G p.Q493E | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV56603934; called by muse, mutect2, varscan2
- NUP214 | c.2142G>C p.Q714H | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100845224, COSV63910409; called by muse, varscan2
- OPCML | c.173C>A p.T58N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as COSV59429349; called by muse, mutect2, varscan2
- OSCP1 | c.205C>G p.Q69E (on ENST00000356637 / NM_001330493.1; = p.Q59E on NM_145047.5) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV52486639; called by muse, mutect2, varscan2
- PCDH17 | c.2208G>C p.E736D | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV64975208; called by muse, mutect2, varscan2
- PCDHB6 | c.1873G>T p.A625S | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV50701759, COSV50709609; called by muse, mutect2, varscan2
- PCSK6 | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV59341754; called by mutect2, varscan2
- PIP4K2C | c.554T>A p.F185Y | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.169); catalogued as COSV61606429; called by muse, mutect2, varscan2
- PKHD1L1 | c.5913T>A p.D1971E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV65745292; called by muse, mutect2, varscan2
- PMM1 | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV53448066; called by muse, varscan2
- PRDM16 | c.2807C>T p.P936L | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs749171035, COSV54594411; called by muse, mutect2, varscan2
- PXDN | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.718); catalogued as COSV53237161; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1790C>G p.S597C | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV54760992; called by muse, mutect2, varscan2
- RBAK | c.854G>C p.G285A | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62331699; called by muse, mutect2, varscan2
- RIMKLB | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV100223820; called by muse, mutect2, varscan2
- SART1 | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as COSV56711700, COSV56712123; called by muse, mutect2, varscan2
- SHPRH | c.553A>G p.M185V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1302967406, COSV51611657; called by muse, mutect2, varscan2
- SLC35B2 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs773882742, COSV51489997; called by muse, mutect2, varscan2
- SLCO4C1 | c.1469+1G>A p.X490_splice | Splice Site (SNP) | VAF 10/56 reads (18%) | catalogued as COSV60516776; called by muse, mutect2, varscan2
- SPATA31A1 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as COSV66533618; called by muse, mutect2, varscan2
- SRPRB | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs951540380, COSV72048441; called by muse, mutect2, varscan2
- SSB | c.704A>C p.K235T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV53626871; called by muse, mutect2, varscan2
- TLCD3A | c.355C>G p.L119V | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56746222; called by muse, mutect2, varscan2
- TNC | c.4775G>A p.G1592D | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.881); catalogued as COSV60785954; called by muse, mutect2, varscan2
- TRIP10 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV57572255; called by muse, mutect2, varscan2
- TTC25 | c.492G>A p.M164I | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs782641073, COSV66368362; called by muse, mutect2, varscan2
- VCX3B | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.178); catalogued as COSV66842875; called by muse, mutect2, varscan2
- VDAC2 | c.536A>C p.N179T | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100040867; called by muse, mutect2, varscan2
- VWA8 | c.1109C>G p.S370C | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as COSV99863798; called by muse, mutect2
- WDR49 | c.1057G>C p.D353H (on ENST00000308378 / NM_001366158.1; = p.D694H on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV100392062, COSV57709026; called by muse, mutect2, varscan2
- XIRP2 | c.8180A>G p.K2727R (on ENST00000628543; = p.K2902R on NM_152381.6) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as COSV54708266; called by muse, mutect2, varscan2
- YIPF6 | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV65855889; called by muse, mutect2, varscan2
- ZBTB32 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV52890950; called by muse, mutect2, varscan2
- ZNF613 | c.1681G>T p.D561Y (on ENST00000293471 / NM_001031721.4; = p.D525Y on NM_024840.4) | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99522871; called by muse, mutect2
- ARID1A | c.3118_3119del p.N1040Sfs*6 | Frame Shift Del (DEL) | VAF 63/173 reads (36%) | called by mutect2, pindel, varscan2
- CBX4 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2
- ELF3 | c.970_971dup p.M324Ifs*2 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- GABRG1 | c.154del p.T52Pfs*17 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- IGKV3-20 | c.124T>C p.S42P | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- RELCH | c.278C>G p.S93* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- RUNX2 | c.1103del p.G368Afs*116 (on ENST00000371438; = p.G346Afs*116 on NM_001015051.3) | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | called by mutect2, pindel, varscan2
- SYNRG | c.2498C>G p.S833C | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPTE | c.562C>T p.P188S (on ENST00000618007 / NM_199261.4; = p.P170S on NM_199259.4) | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); called by muse, mutect2
- AFF3 | c.3666C>T p.S1222= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs1354777142, COSV57857397; called by muse, mutect2, varscan2
- BIRC6 | c.6321A>G p.E2107= | Silent (SNP) | VAF 20/201 reads (10%) | catalogued as COSV70200856; called by muse, mutect2, varscan2
- C10orf90 | c.594C>T p.F198= | Silent (SNP) | VAF 25/153 reads (16%) | catalogued as COSV52957174; called by muse, mutect2, varscan2
- CCR5 | c.249C>T p.V83= | Silent (SNP) | VAF 34/199 reads (17%) | catalogued as COSV52751921; called by muse, mutect2, varscan2
- CD209 | c.387G>T p.R129= | Silent (SNP) | VAF 43/224 reads (19%) | catalogued as COSV52654768, COSV52654986; called by muse, varscan2
- CFAP65 | c.3399G>A p.L1133= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV58562234; called by muse, mutect2, varscan2
- CUL9 | c.5172C>T p.F1724= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as rs781114971, COSV52728616, COSV52729983; called by muse, mutect2, varscan2
- DNAH10 | c.13099C>A p.R4367= (on ENST00000409039; = p.R4306= on NM_207437.3) | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV53018474, COSV53020168; called by muse, mutect2, varscan2
- EFTUD2 | c.1651C>T p.L551= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as COSV68183447; called by muse, mutect2, varscan2
- ENPP3 | c.504A>G p.G168= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV62954673; called by muse, mutect2
- GPR152 | c.618C>G p.L206= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV56886861; called by muse, mutect2, varscan2
- KLHL36 | c.48C>T p.I16= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV50719772; called by muse, mutect2, varscan2
- NPVF | c.567T>C p.D189= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs750807938, COSV56060850; called by mutect2, varscan2
- OPCML | c.174C>A p.T58= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV59429336; called by muse, mutect2, varscan2
- P3H4 | c.573C>T p.V191= | Silent (SNP) | VAF 44/322 reads (14%) | catalogued as COSV58636139; called by muse, mutect2, varscan2
- PTPRA | c.1767G>A p.V589= | Silent (SNP) | VAF 20/168 reads (12%) | catalogued as COSV53783331; called by muse, varscan2
- RTL8C | c.330C>T p.D110= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV57060190; called by muse, mutect2, varscan2
- SIGLEC8 | c.1002G>A p.Q334= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs1436601241, COSV100367199; called by muse, mutect2, varscan2
- SLC5A11 | c.1641C>T p.S547= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as COSV61742078; called by muse, mutect2, varscan2
- SPEG | c.4071C>T p.F1357= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV56671274; called by muse, mutect2, varscan2
- ZNF318 | c.5871T>A p.A1957= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV58933517; called by muse, mutect2, varscan2
- ZNF765 | c.1425C>T p.F475= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as COSV67182743; called by muse, varscan2
